Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3383, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3383-01A (Primary Tumor).

[page 1 of 2]
PHYSICIAN INFORMATION

Sex: Male

CGA - A3 - 3383

SPECIMEN INFO

Collected:

Received:

Reported:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

Left kidney, radical nephrectomy:
Renal carcinoma.

Tumor Characteristics:

1. Histologic type: Clear cell adenocarcinoma.
2. Tumor site: Posterior aspect, mid kidney.
3. Tumor size: 5.0 x 5.0 x 4.5 cm.
4. Macroscopic extent of tumor: Limited to kidney.
5. Nuclear grade: Fuhrman grade: 2/4.
6. Lymphovascular space invasion: Absent.
7. Transcapsular invasion: Absent.
8. Renal vein invasion: Absent.
9. Venacaval invasion: Not resected.
10. Adrenal gland: Not identified.

Surgical Margin Status:

1. Soft tissue margins: Negative for tumor.
2. Ureteral margin: Negative for tumor.
3. Vascular Margins: Negative for tumor.

Lymph Node Status:

1. No lymph nodes identified.

Other Significant Findings:

1. pTNM stage: pT1NXMX.

[page 2 of 2]
CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis:

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

Left kidney

SPECIMEN DATA

GROSS DESCRIPTION:

Received in a single container labeled s a 282 gram left kidney, 13.0 x 9.0 x 6.0 cm in greatest dimension. The capsule is tan-gray translucent displaying an abundant amount of adhered tan-yellow lobular adipose tissue. The posterior wall in the mid body displays a bulging subcapsular mass. The hilar region displays an abundant amount of adhered adipose tissue. A portion of ureter extends 10.0 cm in length and 0.5 cm in diameter. No lymph nodes are found in the hilar region. Bivalving the kidney reveals a pale renal cortex and medulla. The cortex averages 1.0 cm. The specimen displays slightly flattened pyramids and fat filled calices. The well encapsulated tan-yellow lobular mass previously noted is 5.0 x 5.0 x 4.5 cm in greatest dimension and does not appear to grossly invade into the renal pelvis. Samples of this mass have been submitted for genomic studies in six cassettes. No other lesions are grossly noted. No calculi are seen. Representative sections submitted in eight cassettes labeled as follows: vessel and ureter margins--1; inked capsule--2; pelvic wall--3; lesion--4 to 7; normal renal tissue--8.

Source: NCI Genomic Data Commons file e41d7d9d-80be-4f82-b4f7-74ff8ab325d0 (TCGA-A3-3383.02718684-D36D-4C47-A027-A4183BF9BED0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).